Somatic mutation profile of tumor specimen 0DRRTZ from CCDI case PBCFUG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 20.8 years (7,599 days).
Specimen 0DRRTZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9007ac9-15b9-4c3f-be05-0e8299b8ed93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRRTR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2300bcd9-c558-4bb8-8ca2-04fa597f793a

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG2 | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 156/2042 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1227040418; called by muse, mutect2
- PELP1 | c.209del p.M70Sfs*23 | Frame Shift Del (DEL) | VAF 242/667 reads (36%) | catalogued as COSV52585863; called by mutect2, pindel, varscan2
- RBM6 | c.2897A>G p.N966S | Missense Mutation (SNP) | VAF 780/1247 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99805480; called by muse, mutect2, varscan2
- EP400 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 191/415 reads (46%) | called by muse, mutect2, varscan2
- ILRUN | c.796C>T p.Q266* (on ENST00000374023 / NM_024294.4; = p.Q200* on NM_022758.6) | Nonsense Mutation (SNP) | VAF 610/1418 reads (43%) | called by muse, mutect2, varscan2
- RCSD1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 475/1035 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARL6IP5 | c.303C>T p.F101= | Silent (SNP) | VAF 459/1499 reads (31%) | catalogued as rs753914980, COSV56234986; called by muse, mutect2, varscan2
- KMT2D | c.11421G>A p.V3807= | Silent (SNP) | VAF 199/473 reads (42%) | called by muse, mutect2, varscan2
- NYX | c.186C>T p.C62= | Silent (SNP) | VAF 187/207 reads (90%) | called by muse, mutect2, varscan2
- SFRP5 | c.30G>A p.V10= | Silent (SNP) | VAF 99/246 reads (40%) | called by mutect2, varscan2
- CLEC4C | chr12:7747376 C>T | 5'Flank (SNP) | VAF 254/601 reads (42%) | catalogued as rs765156767; called by muse, mutect2, varscan2
- FBXO46 | c.*39C>T | 3'UTR (SNP) | VAF 52/88 reads (59%) | called by muse, mutect2, varscan2
- GPT | c.820-25C>T | Intron (SNP) | VAF 191/370 reads (52%) | called by muse, mutect2, varscan2
- SPIB | c.*24G>A | 3'UTR (SNP) | VAF 87/200 reads (44%) | called by muse, mutect2, varscan2
- TCF4 | c.922+36T>C | Intron (SNP) | VAF 294/626 reads (47%) | called by muse, mutect2, varscan2
- WDPCP | c.1435+84G>A | Intron (SNP) | VAF 32/81 reads (40%) | catalogued as rs908410586; called by muse, mutect2, varscan2
